Somatic mutation profile of tumor specimen TCGA-G9-6361-01A (aliquot TCGA-G9-6361-01A-21D-1961-08) from TCGA case TCGA-G9-6361, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.8 years (22,565 days).
Specimen TCGA-G9-6361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb257b9d-1510-46c8-9192-1b21dd61ec04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6361-10A (Blood Derived Normal), aliquot TCGA-G9-6361-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43480e8f-69a0-44a6-8b84-49c5facec008

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4531C>A p.Q1511K | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as COSV61271071; called by muse, mutect2, varscan2
- AKAP9 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV62342229; called by muse, mutect2, varscan2
- B4GALT1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409572147, COSV101122945, COSV65708575; called by muse, mutect2, varscan2
- C3 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55574786, COSV55574867; called by muse, mutect2
- CDK5RAP3 | c.52+1G>T p.X18_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV58115645; called by muse, mutect2, varscan2
- CTTNBP2 | c.3107C>A p.T1036N | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV50430629; called by muse, mutect2, varscan2
- DHX30 | c.805C>G p.H269D (on ENST00000445061 / NM_138615.3; = p.H230D on NM_014966.3) | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV62395860; called by muse, mutect2, varscan2
- FOCAD | c.4344G>C p.L1448F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.943); catalogued as rs1564233968, COSV58104272; called by muse, mutect2, varscan2
- FRYL | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV51954677; called by muse, mutect2, varscan2
- GK5 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67486257; called by muse, mutect2, varscan2
- HRAS | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs909222512, COSV54244557; called by muse, mutect2, varscan2
- JAKMIP1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1283427409, COSV51533570; called by muse, mutect2, varscan2
- KCNT2 | c.2416A>T p.T806S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as COSV54094919; called by muse, mutect2, varscan2
- KCNT2 | c.758G>T p.W253L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV54094935; called by muse, mutect2, varscan2
- KHDC4 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs893530191, COSV64165385; called by mutect2, varscan2
- KRTAP11-1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as rs199869279; called by muse, mutect2, varscan2
- LUZP4 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV64219350; called by muse, mutect2, varscan2
- MAP3K12 | c.882-1G>C p.X294_splice | Splice Site (SNP) | VAF 25/76 reads (33%) | catalogued as COSV57234581; called by muse, mutect2, varscan2
- OTOP3 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs573473452, COSV60914156; called by muse, mutect2, varscan2
- QTRT1 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759960986, COSV51552203; called by muse, mutect2, varscan2
- RHOC | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV53518674; called by muse, mutect2, varscan2
- SHMT2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.318); catalogued as COSV61073138; called by muse, mutect2, varscan2
- TCF7L1 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56401030; called by muse, mutect2, varscan2
- TINAG | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1365790052, COSV52510550; called by muse, mutect2
- LHFPL3 | c.579del p.F194Lfs*10 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- CLYBL | c.714C>A p.L238= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV59225449; called by muse, mutect2, varscan2
- FAM135B | c.780G>A p.L260= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV52740637; called by muse, mutect2, varscan2
- SCN8A | c.5385C>T p.F1795= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as rs748215769, COSV61981770, COSV61995551; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYT12 | c.942C>T p.N314= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as rs371812825, COSV67354527; called by muse, mutect2, varscan2
- SYT5 | c.432G>A p.S144= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs1044487634, COSV62829625; called by muse, mutect2, varscan2
- TRIM29 | c.519C>T p.C173= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs371202079; called by muse, mutect2, varscan2
